Somatic mutation profile of tumor specimen TCGA-AG-A00H-01A (aliquot TCGA-AG-A00H-01A-01W-A00E-09) from TCGA case TCGA-AG-A00H, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.2 years (27,485 days).
Specimen TCGA-AG-A00H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a832bbc-0310-4f21-8fb8-177b42a71f18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A00H-10A (Blood Derived Normal), aliquot TCGA-AG-A00H-10A-01W-A00E-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96a95b85-f64d-47b8-b990-aba1d57582a7

The open-access MAF lists 86 somatic variants for this specimen: 59 protein-altering or splice-affecting, 21 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 21, Nonsense Mutation 7, RNA 3, Frame Shift Del 2, Frame Shift Ins 2, Intron 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EDNRB | c.823G>A p.V275M (on ENST00000377211 / NM_001201397.1; = p.V185M on NM_000115.5) | Missense Mutation (SNP) | VAF 117/340 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs781214034, CM081580, COSV57520197, COSV57528867; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 75/274 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 32/109 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACKR2 | c.329G>T p.W110L | Missense Mutation (SNP) | VAF 222/725 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56179091; called by muse, mutect2, varscan2
- ADAM2 | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 78/203 reads (38%) | catalogued as rs868563447, COSV55865897; called by muse, mutect2, varscan2
- ADAMTS9 | c.4276G>C p.D1426H | Missense Mutation (SNP) | VAF 38/1008 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); catalogued as rs1337981827; called by muse, mutect2
- ALKBH5 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.073); catalogued as COSV67687219; called by muse, mutect2, varscan2
- ARID1A | c.2368C>T p.Q790* | Nonsense Mutation (SNP) | VAF 28/75 reads (37%) | catalogued as COSV61377388; called by muse, mutect2, varscan2
- ARPP21 | c.2110G>A p.V704M | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.163); catalogued as rs894763514, COSV51802791; called by muse, mutect2, varscan2
- ASIC2 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.871); catalogued as COSV63309139; called by muse, mutect2, varscan2
- ASTN1 | c.3623G>A p.R1208Q | Missense Mutation (SNP) | VAF 96/301 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768973979, COSV62496507; called by muse, mutect2, varscan2
- BPIFB4 | c.155G>A p.R52K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.745); catalogued as rs1406745333, COSV64951829; called by muse, mutect2, varscan2
- C11orf49 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV53568890; called by muse, mutect2, varscan2
- CENPJ | c.2601G>T p.M867I | Missense Mutation (SNP) | VAF 31/520 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV67884048; called by muse, mutect2
- CES1 | c.1285C>T p.P429S (on ENST00000361503 / NM_001025194.2; = p.P428S on NM_001266.5) | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV62088959; called by muse, mutect2, varscan2
- CNOT4 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 11/371 reads (3%) | catalogued as COSV100210943; called by muse, mutect2
- CNTLN | c.3229C>A p.P1077T | Missense Mutation (SNP) | VAF 77/322 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV52089383; called by muse, mutect2, varscan2
- COL12A1 | c.4856C>G p.T1619S | Missense Mutation (SNP) | VAF 143/663 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.105); catalogued as rs757815790, COSV59402802; called by muse, mutect2, varscan2
- COL22A1 | c.3977C>T p.P1326L | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.24); catalogued as rs202129460; called by muse, mutect2, varscan2
- CYFIP2 | c.1882C>T p.H628Y (on ENST00000616178 / NM_001291722.2; = p.H603Y on NM_014376.4) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.784); catalogued as rs1482284867, COSV59046279; called by muse, mutect2, varscan2
- EYA4 | c.815C>A p.S272Y | Missense Mutation (SNP) | VAF 120/503 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV100765593, COSV62057800; called by muse, mutect2, varscan2
- FAM47B | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs1184635361, COSV61452543; called by muse, mutect2, varscan2
- GJA10 | c.1223A>T p.D408V | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs776346674, COSV65355773; called by muse, mutect2, varscan2
- IGHV1-24 | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.246); catalogued as rs1555470218; called by muse, mutect2
- ITGA10 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs587701227, COSV65198194; called by muse, mutect2, varscan2
- KCNB1 | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.606); catalogued as rs554351105, COSV65566168; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNB2 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 154/527 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV73050758; called by muse, mutect2, varscan2
- LONP2 | c.779A>G p.D260G | Missense Mutation (SNP) | VAF 68/482 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1439161266, COSV53524503, COSV53526042; called by muse, mutect2, varscan2
- MACC1 | c.903C>G p.F301L | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV60540521, COSV60545067; called by muse, mutect2, varscan2
- MMP7 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.024); catalogued as rs1181292148, COSV52772820; called by muse, mutect2, varscan2
- MON1B | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.349); catalogued as rs781298641, COSV99941649; called by mutect2, varscan2
- MUC16 | c.20303C>T p.A6768V | Missense Mutation (SNP) | VAF 351/1203 reads (29%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs369202278; called by muse, mutect2, varscan2
- NAA30 | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 72/212 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53649239; called by muse, mutect2, varscan2
- NBEA | c.5225A>T p.N1742I | Missense Mutation (SNP) | VAF 31/389 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV59807202; called by muse, mutect2
- NLGN4X | c.2179G>T p.E727* | Nonsense Mutation (SNP) | VAF 38/63 reads (60%) | catalogued as COSV52018997, COSV52029218; called by muse, mutect2, varscan2
- NLRP7 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759837769, COSV60173232; called by muse, mutect2, varscan2
- OLFM3 | c.301G>T p.E101* (on ENST00000338858 / NM_001288821.1; = p.E81* on NM_058170.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | catalogued as COSV58796676, COSV58801674; called by muse, mutect2, varscan2
- PRKAR1A | c.230C>G p.S77* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV62235070, COSV62236292; called by muse, mutect2, varscan2
- RAB37 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV61196670; called by muse, mutect2, varscan2
- RNF168 | c.528G>T p.E176D | Missense Mutation (SNP) | VAF 100/495 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV58838905; called by muse, mutect2, varscan2
- SACS | c.3175G>C p.E1059Q | Missense Mutation (SNP) | VAF 35/378 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV66544518; called by muse, mutect2
- SLC6A1 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs941588071, COSV55113013; ClinVar: uncertain significance; called by muse, mutect2
- SMAD2 | c.5C>G p.S2W | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100054049, COSV50994528; called by muse, mutect2
- SYNE2 | c.20652dup p.T6885Hfs*15 | Frame Shift Ins (INS) | VAF 6/27 reads (22%) | catalogued as rs770058729; called by mutect2, pindel
- TERF2IP | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 37/350 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs367821647; called by muse, mutect2, varscan2
- TGM5 | c.1259C>A p.T420K (on ENST00000220420 / NM_201631.4; = p.T338K on NM_004245.4) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV55011350; called by muse, mutect2, varscan2
- TMBIM4 | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV53969936; called by muse, mutect2, varscan2
- TRIM33 | c.809G>C p.G270A | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV61824652; called by muse, mutect2, varscan2
- TTC27 | c.1287G>T p.K429N | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV58654971; called by muse, mutect2, varscan2
- ZFHX4 | c.6944A>G p.K2315R | Missense Mutation (SNP) | VAF 104/360 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51479768; called by muse, mutect2, varscan2
- ZRANB1 | c.998C>G p.T333R | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV62843455; called by muse, mutect2, varscan2
- APC | c.1993_1994del p.L665Ifs*8 | Frame Shift Del (DEL) | VAF 102/224 reads (46%) | called by mutect2, pindel, varscan2
- CNKSR2 | c.1810T>C p.Y604H | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DNAJC3 | c.487A>C p.N163H | Missense Mutation (SNP) | VAF 13/339 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- FCGBP | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- IFNA4 | c.497T>A p.V166D | Missense Mutation (SNP) | VAF 25/918 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- LYN | c.1183_1184del p.N395* | Frame Shift Del (DEL) | VAF 25/172 reads (15%) | called by mutect2, pindel, varscan2
- STS | c.635dup p.S213Qfs*41 | Frame Shift Ins (INS) | VAF 70/120 reads (58%) | called by mutect2, varscan2
- TRBV27 | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 144/524 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- ADD3 | c.1335T>C p.T445= | Silent (SNP) | VAF 184/530 reads (35%) | catalogued as COSV53324605; called by muse, mutect2, varscan2
- ALAS1 | c.276G>A p.P92= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as rs775573851, COSV59629031; called by muse, mutect2, varscan2
- APBA1 | c.1092C>T p.T364= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as rs766281107, COSV55233241; called by muse, mutect2
- CEP85L | c.2310T>C p.T770= | Silent (SNP) | VAF 56/228 reads (25%) | catalogued as COSV63826148; called by muse, mutect2, varscan2
- CNNM2 | c.1506C>T p.F502= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs1399748420, COSV63996271; called by muse, mutect2, varscan2
- CRMP1 | c.297C>T p.G99= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV61480875; called by muse, mutect2, varscan2
- CRYBB2 | c.354C>T p.T118= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs748307484, COSV68005656; called by muse, mutect2, varscan2
- CSE1L | c.249A>G p.K83= | Silent (SNP) | VAF 36/236 reads (15%) | catalogued as COSV53703790; called by muse, mutect2, varscan2
- EFCAB6 | c.3459G>A p.P1153= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs142712637; called by muse, mutect2, varscan2
- F8 | c.3342G>A p.S1114= | Silent (SNP) | VAF 167/279 reads (60%) | catalogued as rs200593763, COSV64276817; called by muse, mutect2, varscan2
- GABBR1 | c.1908C>T p.G636= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV63543793; called by muse, mutect2, varscan2
- NPR2 | c.279C>T p.P93= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV61309963; called by muse, mutect2, varscan2
- OR52L1 | c.912G>A p.A304= | Silent (SNP) | VAF 17/137 reads (12%) | catalogued as rs780095253, COSV59985658; called by muse, mutect2, varscan2
- P4HA1 | c.768A>G p.K256= | Silent (SNP) | VAF 22/259 reads (8%) | catalogued as COSV54963929; called by muse, mutect2
- PCDHA4 | c.1863G>A p.P621= | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- PCDHGA11 | c.2292G>A p.S764= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs758742300, COSV53895279; called by muse, mutect2, varscan2
- PHACTR3 | c.1494G>A p.L498= | Silent (SNP) | VAF 34/190 reads (18%) | catalogued as COSV63031795; called by muse, mutect2, varscan2
- SKIV2L | c.1377C>T p.N459= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs377050125; called by muse, varscan2
- SLC15A2 | c.1710G>T p.L570= | Silent (SNP) | VAF 10/282 reads (4%) | called by muse, mutect2
- SP140L | c.936A>T p.G312= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as COSV54746411; called by muse, mutect2, varscan2
- TENM2 | c.2682G>A p.T894= (on ENST00000518659 / NM_001122679.2; = p.T662= on NM_001080428.3) | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs763280815, COSV69137170; called by muse, mutect2, varscan2
- AC244258.1 | n.257C>A | RNA (SNP) | VAF 8/117 reads (7%) | called by muse, mutect2
- AC244258.1 | n.259T>G | RNA (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- CSH1 | c.456+12G>A | Intron (SNP) | VAF 36/102 reads (35%) | catalogued as rs750903185, COSV100298177, COSV100298201, COSV60242731; called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895798 C>A | 5'Flank (SNP) | VAF 26/99 reads (26%) | catalogued as COSV60003668, COSV60004263; called by muse, mutect2, varscan2
- SNORD115-21 | n.28C>A | RNA (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2, varscan2
- TMC5 | c.1049-3382C>T | Intron (SNP) | VAF 50/229 reads (22%) | catalogued as rs140513775; called by muse, mutect2, varscan2
